Gene-level copy-number profile of tumor specimen BLGSP-71-06-00084-01A from CGCI case BLGSP-71-06-00084, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS.
Specimen BLGSP-71-06-00084-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Buccal Mucosa; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5e7c6eb6-1fe3-46e8-a599-5ab125bca635.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-06-00084-99A (granulocytes); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/be2a50c7-bb00-4ef2-9e27-f20695ad6c85

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 60; copy number 1: 28; copy number 2: 58,227; copy number 3: 75.

Homozygous deletions (total copy number 0; autosomes only): 60 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,861,886–88,992,931, 10 genes (within-gene range 0–1): IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8.
- chr2:89,027,171–89,027,731, 1 gene (within-gene range 0–1): IGKV3-11.
- chr14:105,851,705–106,055,998, 46 genes (within-gene range 0–2): IGHM, MIR4539, MIR4507, MIR4538, MIR4537, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3, IGHV4-4, IGHV7-4-1, IGHV2-5, IGHVIII-5-1, IGHVIII-5-2, IGHV3-6.
- chr14:106,088,122–106,108,464, 2 genes (within-gene range 0–2): IGHV3-64D, IGHV5-10-1.
- chr14:106,170,749–106,171,052, 1 gene (within-gene range 0–2): IGHVIII-16-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 28. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
